Somatic mutation profile of tumor specimen TCGA-ET-A39J-01A (aliquot TCGA-ET-A39J-01A-11D-A19J-08) from TCGA case TCGA-ET-A39J, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 23.2 years (8,491 days).
Specimen TCGA-ET-A39J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c5cde3c-122e-44b2-9abb-e6a20a5e7716.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A39J-10A (Blood Derived Normal), aliquot TCGA-ET-A39J-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a102535-0ce7-4a04-982e-d792b87d503e

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CALHM2 | c.374G>C p.G125A | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53294814; called by muse, mutect2, varscan2
- DYNLL1 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV54359558; called by muse, mutect2, varscan2
- HAUS3 | c.715C>G p.Q239E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV54722215; called by muse, mutect2, varscan2
- IL1R1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 121/323 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52105448; called by muse, mutect2, varscan2
- SPTA1 | c.6989+1G>A p.X2330_splice | Splice Site (SNP) | VAF 30/77 reads (39%) | catalogued as COSV63750806; called by muse, mutect2, varscan2
- PHLDB1 | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 6/141 reads (4%) | called by muse, mutect2
- SPTB | c.912del p.I304Mfs*7 | Frame Shift Del (DEL) | VAF 34/126 reads (27%) | called by mutect2, pindel, varscan2
